Surgical pathology report (de-identified scan), TCGA case TCGA-24-1603, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-1603-01A (Primary Tumor).

[page 1 of 2]
80
80
Name:
Address:

TCGA-24-1603

Surg. Path. No.:

DOB:

Sex/Race:

Location:

Hosp. No.:

Taken/Received:

MR No.:
Service:
Surgeon:

DIAGNOSIS

OVARY, LEFT, EXCISION - POORLY DIFFERENTIATED ADENOCARCINOMA,
MIXED PAPILLARY SEROUS AND ENDOMETRIOID TYPE

OVARY, RIGHT, EXCISION - POORLY DIFFERENTIATED ADENOCARCINOMA,
MIXED PAPILLARY SEROUS AND ENDOMETRIOID TYPE

FALLOPIAN TUBE, RIGHT, EXCISION - NO DEFINITE FALLOPIAN TUBE
IDENTIFIED

FALLOPIAN TUBE, LEFT, EXCISION - NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, CERVIX, EXCISION - NO HISTOPATHOLOGIC ABNORMALITY

UTERUS, ENDOMETRIUM, EXCISION - INACTIVE ENDOMETRIUM

UTERUS, MYOMETRIUM, EXCISION - POORLY DIFFERENTIATED ADENOCARCINOMA,
METASTATIC, SEROSAL IMPLANTS
- ADENOMYOSIS

OMENTUM, EXCISION - POORLY DIFFERENTIATED ADENOCARCINOMA,
METASTATIC, CONSISTENT WITH OVARIAN PRIMARY
(SEE SYNOPSIS REPORT)

SPECIMEN(S) SUBMITTED

Part 1: FS1-OVARY, LEFT

Part 2: K1-OVARY, LEFT

Part 3: RIGHT ADNEXA AND UTERUS

Part 4: OMENTUM

HISTORY

The patient is a [REDACTED] with bilateral adnexal masses.
Operative procedure: Total abdominal hysterectomy with bilateral
salpingo-oophorectomy and omentectomy.

[page 2 of 2]
GROSS (continued)

From anterior and posterior cervix; E1 and E2, sections from anterior and posterior endometrium; F1, section from putative right fallopian tube; M1 and M2, section from myometrium to the tumor on the serosa; P1 and P2, sections from the large globular cystic tumor mass.

The fourth container is labelled "omentum" and consists of a slab of omental fat, measuring 19.0 x 9.0 x 1.0 cm. Multiple gray-white, soft tissue nodules are identified, the largest of which measures 1.2 x 1.2 x 1.0 cm.

COMMENT

Sections from both right and left ovaries show a poorly differentiated adenocarcinoma with features of both papillary serous and endometrioid carcinoma. Both ovaries are almost completely replaced by the tumor and show tumor both on the surface and within the stroma. The tumor is represented by large nests, nests, and papillary structures consisting of large cells with a high nuclear-to-cytoplasmic ratio, large hyperchromatic nuclei, and a high mitotic rate approaching approximately 80 mitoses in 20 high power fields including abnormal forms. Sections from the cervix are unremarkable. Sections from the endometrium show an inactive endometrium. The myometrium near the serosa shows a small area of adenomyosis. Large metastatic implants of tumor are present on the serosa of the uterus covering approximately 75% of the surface area. The left fallopian tube shows no histopathologic abnormality while no definite fallopian tube is identified on the right side. It is possible that the attached fallopian tube on the left side has been replaced completely by the tumor. Metastatic tumor implants are present in the omentum. Further details.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT, bilaterally.
2. The HISTOLOGIC DIAGNOSIS is:
Mixed serous adenocarcinoma and endometrial type
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary (synchronous primary tumors)
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODER'S) GRADE of the tumor is:

Source: NCI Genomic Data Commons file f7090419-962c-425e-b72a-e6a3a96f9a4d (TCGA-24-1603.B5EA4CB8-5F2A-4A6D-88ED-F36C1B12E3F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).